Surgical pathology report (de-identified scan), TCGA case TCGA-FA-A4XK, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Asterand, specimen TCGA-FA-A4XK-01A (Primary Tumor).

Gross Description: Tumor is located in Jejunum. It is protruded and ulcerated, occupying circumference with 10x8x3cm in size, soft, white and gray surface.

Microscopic Description: Tumor cells arrange in diffuse, replace glands or intervening in benign glands. The tumor cells are composed of large transformed lymphoid cells and multinuclei giant cells, with hyperchromatic nuclei. Tumor cells are oval or round in shape with scant cytoplasm. Nucleoli is single or multiple. Mitotic figures are common.

Diagnosis Details: Malignant lymphoma, Large B cell, diffuse type. IHC testing was performed; tumor cells are positive for CD20. Tumor cells are negative for CD3 and CKAE1/AE3.

Comments:

Formatted Path Reports: LYMPHOMA

Tumor location: Small intestine, jejunum

Tumor size: 10 x 8 x 3 cm

Tumor features: Ulcerated, diffuse

Specimen type: Diffuse large b-cell lymphoma of the small intestine

Tumor invasion: Unspecified

Lymph nodes: 0/3, mesenteric

Diagnosis Details: Malignant lymphoma, Large B cell, diffuse type.

Comments: IHC testing results: CD20- positive, CD3- negative, CKAE1/AE3- negative

IED-0-3

Lymphoma, Large B cell,
Diffuse NOS 9680/B
Site: Small intestine, jejunum
C17.1
JED 1/10/13

Source: NCI Genomic Data Commons file 57b30b3f-6567-4783-9d50-c8a507f9a1e7 (TCGA-FA-A4XK.05EFF049-BF35-4D89-8968-5442C5FF375A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).